Somatic mutation profile of cancer-model specimen HCM-BROD-0695-C71-85R (Adherent Cell Line, passage 8; aliquot HCM-BROD-0695-C71-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0695-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.3 years (21,646 days).
Specimen HCM-BROD-0695-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5dd880d-349c-4723-8a1f-7169a60e44da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0695-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0695-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6c941c3-ab47-4a55-9a3d-3d039f599b0f

The open-access MAF lists 85 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 52, Silent 18, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATOH1 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 174/346 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024456; called by muse, mutect2, varscan2
- BEND5 | c.1176del p.V393Sfs*46 | Frame Shift Del (DEL) | VAF 82/289 reads (28%) | catalogued as COSV65717200; called by mutect2, pindel, varscan2
- CACNA2D3 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369646799, COSV55525913; called by muse, mutect2, varscan2
- CACNA2D4 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs774106563, COSV54950429; called by muse, mutect2, varscan2
- CARM1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 174/363 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as rs745964402, COSV59002843; called by muse, mutect2, varscan2
- CCDC60 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 144/261 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs912024814, COSV100554949; called by muse, mutect2, varscan2
- CFAP53 | c.1445T>C p.M482T | Missense Mutation (SNP) | VAF 36/864 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs201414884; called by muse, mutect2
- CIP2A | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV99843197; called by muse, mutect2, varscan2
- COL6A5 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 125/351 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as rs368190316; called by muse, mutect2, varscan2
- CSN3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 192/399 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs143899003; called by muse, mutect2, varscan2
- DPF2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs71468699, COSV52889788, COSV99361832; called by muse, mutect2, varscan2
- FOXR1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 156/325 reads (48%) | catalogued as rs572275655, COSV57652282; called by muse, mutect2, varscan2
- MSH4 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs779450051, COSV54201917; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3B | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.572); catalogued as rs756085146, COSV58721568; called by muse, mutect2
- NFE2L1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 178/430 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772276793; called by muse, mutect2, varscan2
- OR5J2 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 195/438 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs200335105; called by muse, mutect2, varscan2
- PCDHB2 | c.717C>A p.D239E | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV52033714; called by muse, mutect2, varscan2
- PIK3CG | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 336/1083 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63255550; called by muse, mutect2, varscan2
- PTEN | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1564568473, COSV64302345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF125 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 168/263 reads (64%) | SIFT tolerated (0.84); PolyPhen benign (0.134); catalogued as rs201216500; called by muse, mutect2, varscan2
- SCN3A | c.5726G>A p.R1909H | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376113629; called by muse, mutect2, varscan2
- SYT14 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs757948488, COSV55049423; called by muse, mutect2, varscan2
- TRIM49C | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 118/415 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1370714257; called by muse, mutect2, varscan2
- TTN | c.58457G>A p.R19486H (on ENST00000591111; = p.R12062H on NM_003319.4) | Missense Mutation (SNP) | VAF 185/433 reads (43%) | PolyPhen benign (0); catalogued as rs201226615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 49/722 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs781601716; called by muse, mutect2
- ADARB2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 347/348 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- AMIGO2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 194/414 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ANKRD44 | c.1160G>C p.C387S | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF17 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 50/686 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ARID1A | c.4394_4395del p.S1465Cfs*25 | Frame Shift Del (DEL) | VAF 334/1001 reads (33%) | called by pindel, varscan2
- CA9 | c.1007del p.C336Lfs*14 | Frame Shift Del (DEL) | VAF 112/357 reads (31%) | called by mutect2, pindel, varscan2
- CCKAR | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHD5 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 336/574 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- CIT | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 162/458 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- COL5A3 | c.947A>T p.N316I | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CTAGE8 | c.943_945del p.L315del | In Frame Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- CYFIP2 | c.3562A>G p.I1188V (on ENST00000616178 / NM_001291722.2; = p.I1163V on NM_014376.4) | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.391); called by muse, mutect2
- DUS3L | c.1879A>T p.S627C | Missense Mutation (SNP) | VAF 162/484 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- EME1 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 178/531 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FAM13B | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 91/210 reads (43%) | called by muse, mutect2, varscan2
- HOXB3 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 261/553 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MAST2 | c.4199_4201del p.P1400del | In Frame Del (DEL) | VAF 234/548 reads (43%) | called by pindel, varscan2
- MYO5B | c.4333del p.Q1445Rfs*41 | Frame Shift Del (DEL) | VAF 126/573 reads (22%) | called by mutect2, pindel, varscan2
- NFKBIL1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 481/1021 reads (47%) | called by muse, mutect2, varscan2
- NKTR | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- NKTR | c.4202C>T p.S1401F | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP1 | c.496C>G p.H166D | Missense Mutation (SNP) | VAF 199/453 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR6T1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 270/513 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OVCH1 | c.2186G>A p.C729Y | Missense Mutation (SNP) | VAF 33/571 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCNX4 | c.2468A>G p.D823G (on ENST00000406854 / NM_001330177.2; = p.D589G on NM_022495.5) | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PIGR | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2R1 | c.3708T>C p.P1236= | Splice Region (SNP) | VAF 115/265 reads (43%) | called by muse, mutect2, varscan2
- PROX2 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 37/431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RADIL | c.537del p.I180* | Frame Shift Del (DEL) | VAF 114/526 reads (22%) | called by mutect2, pindel, varscan2
- RASAL3 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 277/589 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM11 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 250/491 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- RLF | c.4396T>C p.Y1466H | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); called by muse, mutect2
- RPTN | c.139-18_142del p.X47_splice | Splice Site (DEL) | VAF 37/292 reads (13%) | called by mutect2, pindel
- RXFP3 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 432/888 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SENP2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 244/494 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SI | c.2428C>A p.R810S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STARD9 | c.10086T>A p.H3362Q | Missense Mutation (SNP) | VAF 150/440 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TBR1 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 322/836 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TLK1 | c.2077del p.T693Qfs*7 | Frame Shift Del (DEL) | VAF 82/266 reads (31%) | called by mutect2, pindel, varscan2
- TTC4 | c.677_678insA p.K227Qfs*3 | Frame Shift Ins (INS) | VAF 44/188 reads (23%) | called by mutect2, pindel*, varscan2
- ZNF354B | c.1772C>A p.S591* | Nonsense Mutation (SNP) | VAF 69/180 reads (38%) | called by muse, mutect2, varscan2
- AFP | c.597T>C p.V199= | Silent (SNP) | VAF 160/329 reads (49%) | called by muse, mutect2, varscan2
- AMER3 | c.1122C>T p.S374= | Silent (SNP) | VAF 314/649 reads (48%) | catalogued as rs202240427; called by muse, mutect2, varscan2
- ATP2C1 | c.1935A>C p.G645= | Silent (SNP) | VAF 28/467 reads (6%) | called by muse, mutect2
- ATP5F1A | c.102G>A p.R34= | Silent (SNP) | VAF 212/360 reads (59%) | called by muse, mutect2, varscan2
- EME1 | c.1650C>T p.S550= | Silent (SNP) | VAF 174/523 reads (33%) | called by muse, mutect2, varscan2
- EXPH5 | c.4014G>A p.G1338= | Silent (SNP) | VAF 58/479 reads (12%) | catalogued as COSV56200761; called by muse, mutect2, varscan2
- INA | c.603C>T p.R201= | Silent (SNP) | VAF 29/524 reads (6%) | called by muse, mutect2
- KIFAP3 | c.2179T>C p.L727= | Silent (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- KLC1 | c.249G>A p.L83= | Silent (SNP) | VAF 113/235 reads (48%) | catalogued as COSV55808958; called by muse, mutect2, varscan2
- LCN12 | c.432C>T p.L144= | Silent (SNP) | VAF 191/435 reads (44%) | called by muse, mutect2, varscan2
- MMRN1 | c.2889A>T p.L963= | Silent (SNP) | VAF 176/300 reads (59%) | called by mutect2, varscan2
- OR13C3 | c.543C>T p.S181= | Silent (SNP) | VAF 123/495 reads (25%) | catalogued as rs779802213, COSV66165902; called by muse, mutect2, varscan2
- PLA2G2D | c.198C>T p.T66= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as COSV64282032; called by muse, mutect2, varscan2
- SCIN | c.1068C>T p.F356= (on ENST00000297029 / NM_001112706.3; = p.F109= on NM_033128.3) | Silent (SNP) | VAF 143/530 reads (27%) | catalogued as rs200122191; called by muse, mutect2, varscan2
- SEMA4C | c.174G>C p.L58= | Silent (SNP) | VAF 53/607 reads (9%) | called by muse, mutect2
- TM4SF20 | c.57G>T p.L19= | Silent (SNP) | VAF 199/431 reads (46%) | called by muse, mutect2, varscan2
- TRAV17 | c.84T>A p.P28= | Silent (SNP) | VAF 141/282 reads (50%) | called by muse, mutect2, varscan2
- ZAR1L | c.621C>T p.A207= | Silent (SNP) | VAF 245/501 reads (49%) | catalogued as rs370322886; called by muse, mutect2, varscan2
